Surgical pathology report (de-identified scan), TCGA case TCGA-SH-A7BC, project TCGA-MESO (Mesothelioma), tissue source site Papworth Hospital, specimen TCGA-SH-A7BC-01A (Primary Tumor).

Sex: M

Date Collected:
Date Received:
Date Printed:

Copy To:

SPECIMEN DETAILS

Specimen A Parietal pleura
Specimen B Parietal pleura

CLINICAL INFORMATION

Mesothelioma
study
Extensive pleurectomy

ICD-O-3
Mesothelioma, epithelioid, malignant
9052/3
Site: ^{CGLE} Pleura NOS C83.4
^{path} Pleura, parietal C83.4
07/05/2014

MACROSCOPIC DESCRIPTION

Specimen A Parietal pleura

Received in formalin are multiple pieces of thickened fibrous membrane with gelatinous areas measuring in aggregate approximately 10 x 8 x 2 cm and with a single largest piece measuring 5 x 2.5 x 0.3 cm. Multiple random samples taken primarily from the largest pieces. A few areas include adipose tissue.

M in 3 + reserve.

Specimen B Parietal pleura

Received in formalin are multiple thickened fibrous pieces of pleural membrane measuring in aggregate 13 x 10 x 2 cm, the largest single piece measures 6 x 5 x 0.5 cm. There are multiple yellow adipose areas.

M in 3 + reserve.

MICROSCOPIC REPORT

A,B: Strips of pleura extensively infiltrated by an epithelioid malignant mesothelioma.

Reporting Pathologist:
Authorising Pathologist:

Source: NCI Genomic Data Commons file ae5c3fe4-8207-4574-bc3f-6623f1ff8fca (TCGA-SH-A7BC.55D84C00-324B-4CBE-A478-0AD5401C44C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).